Gene-level copy-number profile of tumor specimen C3L-01157-03 from CPTAC case C3L-01157, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,372 days).
Specimen C3L-01157-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e51ff4f2-0099-4e73-98f0-0a9c7222b12f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01157-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/dae7bfa6-0a23-4d6c-b6d8-99c7f315798f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 2: 6,903; copy number 3: 110; copy number 4: 46,266; copy number 5: 3; copy number 6: 4,825; copy number 7: 1; copy number 8: 177; copy number 9: 1; copy number 11: 2; copy number 16: 1; copy number 19: 14; copy number 20: 54; copy number 29: 3.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:87,659,613–87,971,930, 8 genes (within-gene range 0–2): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr14:19,131,842–19,200,279, 3 genes (within-gene range 0–2): AL589182.2, OR11H13P, AL589743.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 75 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:56,712,305–57,006,546, 14 genes, copy number 19: NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, GPR182, ZBTB39.
- chr12:57,216,794–57,959,148, 54 genes, copy number 20: NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr16:28,413,703–28,455,356, 3 genes, copy number 16–29: CDC37P2, AC138894.4, AC138894.2.
- chr16:28,456,372–28,471,175, 1 gene, copy number 29 (within-gene range 6–29): NPIPB7.
- chr16:28,637,654–28,658,682, 1 gene, copy number 9: NPIPB8.
- chr16:28,749,959–28,772,807, 2 genes, copy number 11: AC145285.5, NPIPB9.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
